CCDI case PBCKAC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/b4f1076b-1f7a-46d4-8c00-e36843ab527d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 3.8 years (1,384 days).

Biospecimens (3 samples)
- Sample 0DTM9Q: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTMA0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DTMA2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
